Surgical pathology report (de-identified scan), TCGA case TCGA-HW-7491, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site MSKCC, specimen TCGA-HW-7491-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

old male with history of left facial weakness and large right frontal non-enhancing lesion on MRI.

Specimens Submitted:

1: SP: Right frontal brain lesion

2: SP: Right frontal brain tumor

DIAGNOSIS:

- 1,2) BRAIN, RIGHT FRONTAL LOBE; EXCISION:
- OLIGODENDROGLIOMA, WHO GRADE II.
- P53 IS NEGATIVE ON IMMUNOHISTOCHEMICAL STUDY. THE MIB-1 INDEX DOES NOT EXCEED 3%.
- MATERIAL WILL BE FORWARDED FOR 1p/19q DELETION ANALYSIS.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result

Special Stain

Comment

P53

MIB-1 (Ki-67)

RECUT

IMM RECUT

NEG CONT

Gross Description:

1)The specimen is received fresh for frozen section consultation, labeled "right frontal brain lesion" and consists of an aggregate of tan tissue measuring 1.6 x 0.8 x 0.3 cm. Entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

2). The specimen is received fresh labeled, "Right frontal brain tumor", and consists of multiple pieces of gray tan friable soft tissue measuring 1.2 x 1 x 0.2 cm in aggregate. A sample is given to . The remainder of the specimen is entirely submitted.

Summary of sections:

U-- undesignated

[page 2 of 2]
Summary of Sections:

Part 1: SP: Right frontal brain lesion

Block	Sect. Site	PCs
1	FSC	1

Part 2: SP: Right frontal brain tumor (cdg)

Block	Sect. Site	PCs
1	U	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: RIGHT FRONTAL BRAIN LESION GLIOMA, FAVOR OLIGODENDROGLIOMA. (HUSE)
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 357c3e50-9d58-4b90-919e-043d142579b9 (TCGA-HW-7491.8E93A347-6300-4A66-B5F2-C462867C5801.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).